CCDI case PBBREH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3a5f640a-ca14-46bb-acb3-314a71795798

Demographics
Sex at birth: female.

Diagnoses (1)
1. Central neurocytoma: ICD-O-3 morphology code: 9506/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,343 days).

Biospecimens (3 samples)
- Sample 0DG384: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG38B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGDVF: Tissue type: Tumor; Specimen type: Solid Tissue.
